Somatic mutation profile of tumor specimen C3N-00149-03 (aliquot CPT0084570009) from CPTAC case C3N-00149, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.4 years (24,990 days).
Specimen C3N-00149-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a2c3b2-4df6-402c-8281-3ce0e0f4699a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00149-31 (Blood Derived Normal), aliquot CPT0085310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8649c6ea-502a-4e1a-ad68-33d32cb58c2f

The open-access MAF lists 103 somatic variants for this specimen: 70 protein-altering or splice-affecting, 16 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Frame Shift Del 11, Intron 10, RNA 3, Nonsense Mutation 3, Splice Site 2, 5'UTR 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 272/556 reads (49%) | catalogued as rs5030829, CM156382, CM941369, COSV56543353, COSV56543426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AOC1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs867599399; called by muse, mutect2, varscan2
- APOB | c.12531del p.V4178Lfs*7 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV51938628; called by mutect2, pindel, varscan2
- ATP6V0A2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1295585374, COSV100376830; called by muse, mutect2, varscan2
- CACNA1H | c.6769C>T p.R2257W | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770202267; ClinVar: uncertain significance; called by mutect2, varscan2
- CYLC1 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV61414494; called by muse, mutect2, varscan2
- DENND4A | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs1350242757; called by muse, mutect2, varscan2
- DMD | c.6862C>A p.Q2288K | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967525950, CM103845; called by muse, mutect2, varscan2
- IGSF22 | c.1533G>A p.E511= | Splice Region (SNP) | VAF 32/137 reads (23%) | catalogued as rs1412949342; called by muse, mutect2, varscan2
- INTS8 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1311719361; called by muse, mutect2, varscan2
- MMP17 | c.1059C>A p.Y353* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as rs1314106394; called by muse, mutect2, varscan2
- OLIG1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1457760135, COSV60737713; called by muse, varscan2
- PCMTD1 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62124592; called by muse, mutect2, varscan2
- PKD1L1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs1348702474; called by muse, mutect2, varscan2
- RBM48 | c.731del p.L244Cfs*6 | Frame Shift Del (DEL) | VAF 56/220 reads (25%) | catalogued as rs770281416; called by mutect2, pindel, varscan2
- SEMA5B | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99533137; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050762, CM159806, COSV55442586, COSV55450248; called by muse, mutect2, varscan2
- TRPC7 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs536224426; called by muse, mutect2, varscan2
- TTI1 | c.293del p.S98* | Frame Shift Del (DEL) | VAF 85/342 reads (25%) | catalogued as COSV65060289, COSV65063743; called by mutect2, pindel, varscan2
- ABL1 | c.3016A>C p.I1006L | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATP6V0A2 | c.497_521+3del | Frame Shift Del (DEL) | VAF 30/208 reads (14%) | called by mutect2, pindel
- BAP1 | c.2057-1G>C p.X686_splice | Splice Site (SNP) | VAF 137/273 reads (50%) | called by muse, mutect2, varscan2
- C3 | c.4187A>T p.Q1396L | Missense Mutation (SNP) | VAF 129/397 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CALR | c.35_45del p.L12Rfs*44 | Frame Shift Del (DEL) | VAF 102/552 reads (18%) | called by mutect2, pindel, varscan2
- CCDC63 | c.1108T>G p.L370V | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDC42EP4 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH11 | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 110/458 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CPEB4 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- DENND4A | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DLC1 | c.3167+1G>A p.X1056_splice (on ENST00000276297 / NM_001348081.2; = p.X619_splice on NM_006094.5) | Splice Site (SNP) | VAF 14/81 reads (17%) | called by mutect2, varscan2
- DTNB | c.1430C>A p.T477K | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EIF2AK1 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EXPH5 | c.3443del p.D1148Vfs*5 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- FAM126B | c.695T>G p.L232W | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FER1L5 | c.5717A>T p.K1906M (on ENST00000623019; = p.K1870M on NM_001293083.2) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FYB1 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCG | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GRM1 | c.2647del p.A883Qfs*35 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | called by mutect2, pindel, varscan2
- GTSE1 | c.1569C>G p.S523R | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- HIPK1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HK1 | c.2390T>C p.L797P | Missense Mutation (SNP) | VAF 113/446 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ICE1 | c.3739A>T p.N1247Y | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IL4R | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LZTS2 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPK8IP3 | c.3641G>T p.R1214M | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MED15 | c.1699A>G p.K567E (on ENST00000263205 / NM_001003891.3; = p.K527E on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTX1 | c.784del p.W262Gfs*2 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | called by mutect2, pindel, varscan2
- MYDGF | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- N4BP2L2 | c.2665A>G p.I889V (on ENST00000674422; = p.I460V on NM_033111.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV2 | c.1418C>A p.T473N (on ENST00000396087 / NM_001244963.2; = p.T450N on NM_145117.5) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL1 | c.1869del p.F623Lfs*46 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- NDUFAF7 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NIPBL | c.96_120del p.L32Ffs*7 | Frame Shift Del (DEL) | VAF 17/214 reads (8%) | called by mutect2, pindel
- OS9 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PIK3R3 | c.758T>A p.I253N | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PRDX1 | c.267dup p.T90Yfs*3 | Frame Shift Ins (INS) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1393A>T p.N465Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PYGM | c.31del p.R11Efs*15 | Frame Shift Del (DEL) | VAF 45/170 reads (26%) | called by mutect2, pindel, varscan2
- RSU1 | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXRB | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAP30BP | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SPINK5 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 86/397 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- STAB1 | c.4184A>T p.Q1395L | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRO | c.2554A>T p.T852S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTC9 | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- USP21 | c.928A>C p.M310L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- VWDE | c.3542G>C p.C1181S | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF532 | c.3383A>T p.E1128V | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF644 | c.3646T>G p.L1216V | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- BFAR | c.150G>T p.G50= | Silent (SNP) | VAF 99/385 reads (26%) | called by muse, mutect2, varscan2
- CYRIB | c.267A>G p.K89= | Silent (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1158C>T p.T386= | Silent (SNP) | VAF 19/318 reads (6%) | catalogued as rs539081624; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- DMXL1 | c.7473G>T p.R2491= | Silent (SNP) | VAF 55/161 reads (34%) | called by muse, mutect2, varscan2
- DNAH9 | c.7737G>T p.L2579= | Silent (SNP) | VAF 28/88 reads (32%) | called by mutect2, varscan2
- DOCK2 | c.1872T>C p.R624= | Silent (SNP) | VAF 78/179 reads (44%) | called by muse, mutect2, varscan2
- LTN1 | c.2481C>T p.A827= | Silent (SNP) | VAF 55/181 reads (30%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.606G>A p.P202= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs771836602; called by muse, mutect2, varscan2
- NBEAL1 | c.1675C>A p.R559= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV101495615; called by muse, mutect2, varscan2
- NME4 | c.468G>A p.V156= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs751493049; called by muse, mutect2, varscan2
- PIWIL4 | c.1782G>A p.K594= | Silent (SNP) | VAF 46/291 reads (16%) | called by muse, mutect2, varscan2
- PRRC2B | c.2508T>C p.N836= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- SDHAF2 | c.213C>T p.L71= | Silent (SNP) | VAF 104/331 reads (31%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.85C>A p.R29= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV100764909, COSV63472064; called by muse, mutect2, varscan2
- ZNHIT2 | c.183C>T p.P61= | Silent (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1593C>G p.R531= (on ENST00000252463; = p.R586= on NM_032805.3) | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- AMN | c.1007-38C>T | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs1174452449; called by muse, mutect2, varscan2
- CRYM | c.674-34T>C | Intron (SNP) | VAF 81/289 reads (28%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+830C>T | Intron (SNP) | VAF 18/88 reads (20%) | catalogued as rs1048716567; called by muse, mutect2, varscan2
- MOG | c.731-218G>A | Intron (SNP) | VAF 77/192 reads (40%) | called by muse, mutect2, varscan2
- NBPF7 | n.867C>G | RNA (SNP) | VAF 40/186 reads (22%) | catalogued as rs1171243133; called by muse, mutect2, varscan2
- NBPF9 | c.2476+731G>T | Intron (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9155039 del A | 5'Flank (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- RAD23A | c.-73C>T | 5'UTR (SNP) | VAF 48/173 reads (28%) | catalogued as rs960563311; called by muse, mutect2, varscan2
- RPL23AP42 | n.238C>A | RNA (SNP) | VAF 41/288 reads (14%) | catalogued as rs1190429890; called by muse, mutect2, varscan2
- RRP7A | c.217-109G>A | Intron (SNP) | VAF 64/206 reads (31%) | called by muse, mutect2, varscan2
- RYR3 | c.10023+9C>A | Intron (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- SEMA4C | c.1673-23C>T | Intron (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- SH2D6 | n.652G>A | RNA (SNP) | VAF 67/300 reads (22%) | catalogued as rs755907033, COSV61064383; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3461C>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- SYTL5 | c.1155+610G>A | Intron (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- UBR7 | c.*426T>G | 3'UTR (SNP) | VAF 131/338 reads (39%) | called by muse, mutect2, varscan2
- VLDLR | c.-380G>T | 5'UTR (SNP) | VAF 89/165 reads (54%) | called by muse, mutect2, varscan2
